CCDI case PBCWAE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/0d3151e2-6ffa-43b0-8719-516765d970e4

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Sample 0E1SC1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E1SCF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
